Gene-level copy-number profile of tumor specimen TCGA-AC-A2FE-01A from TCGA case TCGA-AC-A2FE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 62.3 years (22,746 days).
Specimen TCGA-AC-A2FE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.dfc59958-404b-4e0e-9950-9c120f6956c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A2FE-11B (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e209909-7c65-446f-989c-b4b5a45809c6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 59; copy number 2: 5,329; copy number 4: 48,010; copy number 6: 6,195; copy number 8: 6; copy number 10: 39; copy number 11: 33; copy number 15: 93; copy number 17: 40; copy number 22: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A2FE-01A-11D-A19X-01): tumor purity 0.37, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 221 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:115,270,767–115,481,572, 6 genes, copy number 10: AL049825.1, NGF-AS1, NGF, AL512638.3, AL512638.1, AL512638.2.
- chr5:30,248,350–40,067,200, 167 genes, copy number 11–22 (broad region; genes not listed).
- chr5:42,423,439–44,413,989, 48 genes, copy number 10–17: GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1.

Autosomal genes at a single copy (total copy number 1): 59. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
